Somatic mutation profile of tumor specimen ALCH-B376-TTP1-A (aliquot ALCH-B376-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B376, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.4 years (27,888 days).
Specimen ALCH-B376-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70e4070d-c190-48e3-8fee-75985f8b6ea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B376-NB1-A (Blood Derived Normal), aliquot ALCH-B376-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cca6b39-212c-416a-bef5-e7b46ca2c002

The open-access MAF lists 772 somatic variants for this specimen: 538 protein-altering or splice-affecting, 143 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 475, Silent 143, Intron 45, Nonsense Mutation 27, Frame Shift Del 14, Splice Site 13, RNA 12, 3'UTR 12, 5'UTR 9, 5'Flank 8, 3'Flank 5, Frame Shift Ins 3.

Variants (750 of 772; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563867899, CM103705, COSV52828614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 640/1185 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPHS1 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833961, CM990952, COSV62287237; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 46/300 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3427T>G p.S1143A | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs772355982; called by muse, mutect2, varscan2
- ADAMTS12 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61259397, COSV61263423; called by muse, varscan2
- ADCY4 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs200743091, COSV60257963; called by muse, mutect2, varscan2
- ADGRG3 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV59652579; called by muse, mutect2, varscan2
- ADH5 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs1425380309; called by muse, mutect2, varscan2
- AGPAT1 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV61248184; called by muse, mutect2, varscan2
- AHNAK2 | c.4937T>G p.L1646R | Missense Mutation (SNP) | VAF 71/481 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765278698; called by muse, mutect2, varscan2
- AP3D1 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV61429645; called by muse, mutect2
- ARMC9 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs748686282; called by muse, mutect2, varscan2
- ASB1 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs768359941; called by muse, mutect2
- ATP2C1 | c.2126+1G>T p.X709_splice | Splice Site (SNP) | VAF 59/557 reads (11%) | catalogued as CS043121; called by muse, mutect2, varscan2
- ATP8B1 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99377953; called by muse, mutect2, varscan2
- B3GNTL1 | c.833G>C p.R278P | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57947172; called by muse, mutect2, varscan2
- B4GALT4 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63296035; called by muse, mutect2, varscan2
- BIRC7 | c.873C>A p.S291R (on ENST00000217169 / NM_139317.3; = p.S273R on NM_022161.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs771268817, COSV99416977; called by muse, mutect2, varscan2
- C1QB | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.403); catalogued as COSV59245535; called by muse, mutect2, varscan2
- C2orf42 | c.390A>C p.E130D | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs763505710; called by muse, mutect2, varscan2
- CABP1 | c.654+2T>A p.X218_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV57481985; called by muse, mutect2, varscan2
- CACNA1E | c.4408C>A p.R1470S | Missense Mutation (SNP) | VAF 70/637 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV62409697; called by muse, mutect2, varscan2
- CAPN10 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54376280; called by muse, mutect2
- CAV3 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as CM010790, COSV57478483; called by muse, mutect2, varscan2
- CCDC114 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196621; called by muse, mutect2, varscan2
- CCDC158 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as rs767889035, COSV63092560; called by muse, mutect2, varscan2
- CCDC180 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs746559519; called by muse, mutect2, varscan2
- CD1B | c.782G>T p.W261L | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63804988; called by muse, mutect2
- CD200R1L | c.787A>T p.R263W | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV68003926; called by muse, mutect2, varscan2
- CD300A | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 36/457 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV60409388; called by muse, mutect2
- CD5L | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63822781; called by muse, mutect2, varscan2
- CDH23 | c.7221C>G p.Y2407* | Nonsense Mutation (SNP) | VAF 30/252 reads (12%) | catalogued as CM140436; called by muse, mutect2, varscan2
- CDK20 | c.781G>T p.A261S (on ENST00000325303 / NM_001039803.3; = p.A240S on NM_012119.4) | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as rs182185602; called by muse, mutect2, varscan2
- CFHR2 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 112/600 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199608225; called by muse, mutect2, varscan2
- CFHR5 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1198385422; called by muse, mutect2, varscan2
- COL18A1 | c.1765G>T p.V589L (on ENST00000359759 / NM_130444.3; = p.V354L on NM_030582.4) | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV62703577; called by muse, mutect2, varscan2
- CSTF2T | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as rs757615922; called by muse, mutect2
- CYP4F3 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55414219; called by muse, mutect2, varscan2
- DCSTAMP | c.1338G>C p.K446N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1171713070; called by muse, mutect2
- DEFB121 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as COSV100889982; called by muse, mutect2
- DEFB124 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58343834; called by muse, mutect2, varscan2
- DISP3 | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV99607458, COSV99609990; called by muse, mutect2
- DYSF | c.3843+2T>C p.X1281_splice | Splice Site (SNP) | VAF 24/198 reads (12%) | catalogued as CS103812; called by muse, mutect2, varscan2
- EBLN1 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.398); catalogued as COSV69370242; called by muse, mutect2, varscan2
- EHMT1 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs576113368, COSV58379033; called by muse, mutect2, varscan2
- EPHB6 | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375010348, COSV101235939; called by muse, mutect2
- EPHB6 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV67421206; called by muse, mutect2, varscan2
- ERCC8 | c.1168G>A p.D390N (on ENST00000265038; = p.D371N on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/766 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV54015578; called by muse, mutect2
- EYS | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 37/428 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV100677222; called by muse, mutect2
- F9 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54381694; called by muse, mutect2, varscan2
- FAM50B | c.159C>A p.Y53* | Nonsense Mutation (SNP) | VAF 21/183 reads (11%) | catalogued as COSV66655255; called by muse, mutect2, varscan2
- FCRL3 | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63840220, COSV63843740; called by muse, mutect2
- FKTN | c.1203del p.W401* | Frame Shift Del (DEL) | VAF 221/1201 reads (18%) | catalogued as COSV56308302; called by mutect2, pindel, varscan2
- GLI2 | c.4657T>G p.S1553A (on ENST00000361492 / NM_001374353.1; = p.S1570A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58037536; called by muse, mutect2, varscan2
- GLYATL2 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs1422218067; called by muse, mutect2, varscan2
- GPR50 | c.635G>T p.W212L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV54439333; called by muse, mutect2, varscan2
- GRIK2 | c.1714T>G p.L572V | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV100029366; called by muse, mutect2, varscan2
- GRIN3B | c.3077G>C p.R1026T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs762521662; called by mutect2, varscan2
- GSTO1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV63846561; called by muse, mutect2, varscan2
- GTF2H3 | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV57460097; called by muse, mutect2, varscan2
- H3-4 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs151071964, COSV64210841; called by muse, mutect2, varscan2
- HCN1 | c.1551C>A p.H517Q | Missense Mutation (SNP) | VAF 66/868 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100302170, COSV57494940; called by muse, mutect2
- HECW1 | c.2232C>G p.S744R | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV101224118; called by muse, mutect2, varscan2
- HERC1 | c.4642A>G p.M1548V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781486079; called by muse, mutect2
- IFI27L2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779353746, COSV99032030; called by muse, mutect2, varscan2
- IFT172 | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 47/350 reads (13%) | catalogued as COSV53136505; called by muse, mutect2, varscan2
- IGHM | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 63/531 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782090515; called by muse, mutect2, varscan2
- IGKV2-30 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1431949826; called by mutect2, varscan2
- IL6R | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as rs557934512; called by muse, mutect2, varscan2
- IRAG2 | c.2968A>G p.T990A (on ENST00000636465; = p.T35A on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/936 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs1448928129; called by muse, mutect2
- KCNK15 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65720692; called by muse, mutect2, varscan2
- KIF1A | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.72); catalogued as COSV57484090; called by muse, mutect2, varscan2
- KLHDC7A | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334960675; called by muse, mutect2, varscan2
- KLHL42 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67145605, COSV67145877; called by muse, varscan2
- LAMA4 | c.2034A>C p.E678D (on ENST00000230538 / NM_001105206.3; = p.E671D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/1184 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs782601311; called by muse, mutect2
- LRP1B | c.10723C>A p.H3575N | Missense Mutation (SNP) | VAF 88/875 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV67219891; called by muse, mutect2, varscan2
- LRRTM1 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV54440026; called by muse, mutect2, varscan2
- MCM6 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1313858994, COSV51467700, COSV51470647; called by muse, varscan2
- MEPE | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63072319, COSV63074433; called by muse, mutect2, varscan2
- MRPS27 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs1286400252; called by muse, mutect2, varscan2
- MTFR2 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 80/670 reads (12%) | catalogued as COSV100886688; called by muse, mutect2, varscan2
- MUC16 | c.12062G>T p.S4021I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs764106795, COSV67456375; called by muse, mutect2, varscan2
- MUC4 | c.16085T>G p.L5362R (on ENST00000463781 / NM_018406.7; = p.L1126R on NM_004532.6) | Missense Mutation (SNP) | VAF 36/570 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1241652108; called by muse, mutect2
- MXRA5 | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV54233569, COSV54252645; called by muse, mutect2, varscan2
- MYBL1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV72918686; called by muse, mutect2
- MYH7B | c.3862C>A p.R1288S | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52685079; called by muse, mutect2, varscan2
- MYO1A | c.1624C>T p.L542F | Missense Mutation (SNP) | VAF 77/643 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55654308; called by muse, mutect2, varscan2
- NES | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV63960770, COSV63963471; called by muse, mutect2, varscan2
- NT5E | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs1338053146; called by muse, mutect2
- OR10R2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 78/816 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1212879955, COSV63769320; called by muse, mutect2
- OR2M5 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 75/747 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV63547069; called by muse, mutect2, varscan2
- OR4D5 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs758981994, COSV100189652; called by muse, mutect2, varscan2
- OR4D5 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV58306447; called by muse, mutect2, varscan2
- OR52E2 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100384931; called by muse, mutect2, varscan2
- OR5AC2 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV62279302, COSV62279453; called by muse, mutect2
- OR5H6 | c.887T>A p.V296D (on ENST00000642105; = p.V280D on NM_001005479.2) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67351654; called by muse, mutect2
- OR5K1 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 60/481 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV60304034; called by muse, mutect2, varscan2
- OR8K1 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54401541; called by muse, mutect2, varscan2
- OR9G1 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1483217289; called by muse, mutect2
- P2RY8 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184099; called by muse, mutect2, varscan2
- PARP14 | c.1982T>C p.L661P | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1277703669; called by muse, mutect2
- PCDH15 | c.5241del p.P1749Lfs*95 | Frame Shift Del (DEL) | VAF 34/307 reads (11%) | catalogued as CM1515075, COSV57267894; called by mutect2, varscan2
- PCDHA7 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65342685; called by muse, varscan2
- PCDHA9 | c.2036C>A p.S679* | Nonsense Mutation (SNP) | VAF 47/457 reads (10%) | catalogued as COSV104429944; called by muse, mutect2, varscan2
- PDGFD | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1035466089, COSV56377338; called by muse, mutect2, varscan2
- PDZD2 | c.3181G>T p.D1061Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as COSV56875878; called by muse, mutect2, varscan2
- PHF21A | c.1832T>C p.M611T (on ENST00000418153 / NM_001101802.3; = p.M565T on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.207); catalogued as rs1298933785; called by muse, mutect2, varscan2
- PIK3R5 | c.2411A>C p.K804T | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52659043; called by muse, mutect2, varscan2
- PKHD1 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 87/685 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as CM051141; called by muse, mutect2, varscan2
- PNLIPRP3 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs200331020; called by muse, mutect2, varscan2
- PPP1R3A | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV99034355; called by muse, mutect2, varscan2
- PPP1R9A | c.1310T>C p.M437T | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs769120175; called by muse, mutect2, varscan2
- PRUNE2 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs571284252; called by muse, mutect2, varscan2
- PSG4 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV54935927, COSV54937032; called by muse, mutect2, varscan2
- PSG6 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as COSV51839368; called by muse, mutect2, varscan2
- PSG8 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs770054634; called by muse, mutect2, varscan2
- PTPN23 | c.3230A>G p.Q1077R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1226979230; called by muse, mutect2, varscan2
- PXDN | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs200731840, COSV53229398; called by muse, mutect2, varscan2
- RARS1 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99199074; called by muse, mutect2
- RASIP1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs765840544; called by muse, mutect2
- RDH14 | c.767G>T p.R256M | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67119210; called by muse, mutect2, varscan2
- REG1A | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52069923; called by muse, mutect2, varscan2
- REG3A | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV59409338; called by muse, mutect2, varscan2
- RPL13A | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs746759643; called by muse, mutect2
- RTTN | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219589196; called by muse, mutect2
- SAFB2 | c.2824C>T p.H942Y | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV53041994; called by muse, mutect2, varscan2
- SCARA5 | c.1013G>T p.R338I | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV57276196; called by muse, mutect2, varscan2
- SEL1L | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1049585750, COSV100377730; called by muse, mutect2, varscan2
- SEMA7A | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs751493600, COSV99029468; called by muse, mutect2, varscan2
- SLC4A5 | c.1910A>T p.E637V | Missense Mutation (SNP) | VAF 86/539 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100698007; called by muse, mutect2, varscan2
- SOHLH1 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.011); catalogued as COSV53682584; called by muse, mutect2, varscan2
- SRRT | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52342448; called by muse, mutect2
- STK32A | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60423389; called by muse, mutect2, varscan2
- TAS2R39 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.862); catalogued as COSV71470799; called by muse, mutect2, varscan2
- TBX3 | c.911G>T p.R304L (on ENST00000257566 / NM_016569.4; = p.R284L on NM_005996.4) | Missense Mutation (SNP) | VAF 81/868 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV57469903; called by muse, mutect2
- TENM4 | c.6434T>G p.F2145C | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1047870015; called by muse, mutect2, varscan2
- TH | c.838G>T p.G280W (on ENST00000381178 / NM_199292.3; = p.G249W on NM_000360.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs749133549; called by muse, mutect2, varscan2
- TJP2 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs752656233; called by muse, mutect2, varscan2
- TKTL2 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54920967; called by muse, mutect2, varscan2
- TLL2 | c.2805C>A p.F935L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100780575; called by muse, mutect2, varscan2
- TMEM181 | c.1322A>C p.E441A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1562317524; called by mutect2, varscan2
- TMEM74 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52464262; called by muse, mutect2, varscan2
- TOX2 | c.760G>T p.E254* (on ENST00000358131 / NM_001098798.2; = p.E203* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV57891308; called by muse, mutect2, varscan2
- TPK1 | c.503del p.G168Efs*7 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | catalogued as COSV63636997; called by mutect2, pindel, varscan2
- TULP4 | c.3115C>T p.Q1039* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100893223; called by muse, mutect2
- TXLNB | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62727219, COSV62727224; called by muse, mutect2
- UNC79 | c.6359A>G p.N2120S (on ENST00000393151 / NM_001346218.2; = p.N1943S on NM_020818.5) | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs745443735; called by muse, mutect2
- URB2 | c.3465G>T p.Q1155H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99271700; called by muse, mutect2, varscan2
- WDR87 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58194671; called by muse, mutect2, varscan2
- ZFHX4 | c.6310G>C p.A2104P | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.288); catalogued as COSV51479738; called by muse, mutect2, varscan2
- ZNF208 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV68106889; called by muse, mutect2
- ZNF367 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53561770; called by muse, mutect2
- ZNF727 | c.127T>A p.L43M | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101473407; called by muse, mutect2, varscan2
- ZP4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs376995776; called by muse, mutect2, varscan2
- ABCA6 | c.3389G>T p.W1130L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCA9 | c.991A>C p.T331P | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABLIM1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2
- ACACA | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.713); called by muse, varscan2
- ACOT7 | c.838T>G p.F280V (on ENST00000377855 / NM_181864.3; = p.F270V on NM_007274.4) | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACP7 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACTRT2 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, varscan2
- ADAM17 | c.1023A>C p.Q341H | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- ADAMTS4 | c.1085A>C p.E362A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADARB1 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRF2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 5/67 reads (7%) | PolyPhen benign (0.36); called by muse, mutect2
- ADGRL3 | c.3555G>T p.M1185I (on ENST00000506720 / NM_001322402.2; = p.M1117I on NM_015236.6) | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2
- AFTPH | c.1383T>G p.F461L | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKR1B1 | c.352-2A>T p.X118_splice | Splice Site (SNP) | VAF 70/697 reads (10%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.2327T>A p.L776Q | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALK | c.1058G>T p.R353M | Missense Mutation (SNP) | VAF 79/678 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ALPK1 | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- AMPD3 | c.1465T>C p.F489L (on ENST00000396553 / NM_001025389.2; = p.F498L on NM_000480.3) | Missense Mutation (SNP) | VAF 68/592 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ANK2 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 116/970 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.3595C>A p.Q1199K | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD13B | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANKRD20A4P | c.1153-1G>A p.X385_splice | Splice Site (SNP) | VAF 15/431 reads (3%) | called by muse, mutect2
- ANKRD33B | c.173T>C p.F58S | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD42 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AP1B1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AP1M1 | c.430A>T p.T144S | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APPBP2 | c.896T>G p.L299R | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- ARFGEF3 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP26 | c.2054G>T p.S685I | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP32 | c.2054C>G p.S685* (on ENST00000310343 / NM_001378025.1; = p.S336* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.1778-1G>T p.X593_splice | Splice Site (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2
- ARHGAP5 | c.3085G>C p.D1029H | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ARHGEF11 | c.2811G>C p.Q937H | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF16 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- ARHGEF33 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARNT | c.920A>T p.H307L | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ASTL | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ATF5 | c.522A>C p.E174D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 88/742 reads (12%) | called by pindel, varscan2
- B3GALNT1 | c.654T>G p.F218L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BAHCC1 | c.3257-2A>T p.X1086_splice | Splice Site (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- BEST3 | c.1534G>T p.V512L | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BFSP1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BRSK1 | c.2130G>T p.Q710H | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C11orf87 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- C16orf96 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- C1orf194 | c.153del p.T52Qfs*5 (on ENST00000369948 / NM_001245025.3; = p.T40Qfs*5 on NM_001122961.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/475 reads (11%) | called by mutect2, pindel, varscan2
- C5AR2 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- C9orf64 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1C | c.2013G>T p.Q671H | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAMK1 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP3 | c.1568C>A p.P523H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by mutect2, varscan2
- CASK | c.937T>G p.S313A | Missense Mutation (SNP) | VAF 102/522 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASKIN1 | c.717del p.L240Cfs*10 | Frame Shift Del (DEL) | VAF 37/131 reads (28%) | called by mutect2, pindel, varscan2
- CASP10 | c.1436dup p.T480Dfs*15 | Frame Shift Ins (INS) | VAF 55/497 reads (11%) | called by mutect2, pindel, varscan2
- CCDC158 | c.2321T>G p.L774R | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC168 | c.19344del p.T6450Lfs*17 | Frame Shift Del (DEL) | VAF 42/351 reads (12%) | called by mutect2, pindel, varscan2
- CCDC180 | c.1707C>A p.Y569* | Nonsense Mutation (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- CCDC62 | c.290A>C p.E97A | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCT8L2 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CD177 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- CD300E | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CDC20B | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 66/695 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.386); called by muse, mutect2
- CDH18 | c.555T>A p.D185E | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH19 | c.1997G>T p.R666L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CDH6 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 59/662 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- CEACAM3 | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CECR2 | c.3809A>T p.E1270V (on ENST00000342247 / NM_001290047.2; = p.E1086V on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CELSR2 | c.6928G>A p.E2310K | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CEP162 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 66/643 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP164 | c.2620A>G p.R874G | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CEP170B | c.1392G>C p.R464S (on ENST00000453495; = p.R393S on NM_015005.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERKL | c.1675T>A p.*559Kext*? (on ENST00000339098 / NM_001030311.2; = p.*533Kext*16 on NM_201548.5) | Nonstop Mutation (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- CFAP99 | c.335T>A p.V112E | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFHR4 | c.1564A>G p.M522V (on ENST00000367416 / NM_001201551.2; = p.M276V on NM_006684.5) | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CHERP | c.2408A>C p.K803T | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CHRNA1 | c.467A>T p.Q156L (on ENST00000261007 / NM_001039523.3; = p.Q131L on NM_000079.4) | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CLTC | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTRL | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- COL14A1 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- COL19A1 | c.2346T>A p.P782= | Splice Region (SNP) | VAF 41/352 reads (12%) | called by muse, mutect2, varscan2
- COL6A1 | c.722del p.N241Ifs*60 | Frame Shift Del (DEL) | VAF 41/304 reads (13%) | called by mutect2, pindel, varscan2
- COL9A1 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COX14 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPA6 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 52/445 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CRB1 | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 98/475 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CSF1R | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- CSMD2 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.6395C>A p.P2132H (on ENST00000297405 / NM_001363185.1; = p.P2028H on NM_052900.3) | Missense Mutation (SNP) | VAF 44/608 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2
- CSMD3 | c.1858G>T p.V620L (on ENST00000297405 / NM_001363185.1; = p.V516L on NM_052900.3) | Missense Mutation (SNP) | VAF 68/779 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); called by muse, mutect2
- CWH43 | c.1671C>G p.D557E | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP39A1 | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DBNL | c.1035G>T p.E345D (on ENST00000448521 / NM_001014436.3; = p.E346D on NM_014063.7) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCHS1 | c.6250G>T p.G2084W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCLK1 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DDI2 | c.376A>C p.T126P | Missense Mutation (SNP) | VAF 61/746 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- DDX47 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DENND1A | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DENND3 | c.592T>G p.F198V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DEPDC4 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- DHX29 | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 23/431 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DLK2 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DNAJC6 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOCK6 | c.3816G>T p.W1272C | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK6 | c.45-2A>T p.X15_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- DPP10 | c.1362-1G>T p.X454_splice | Splice Site (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- DSG3 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DUSP28 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DVL1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ECE1 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGFLAM | c.988A>G p.R330G | Missense Mutation (SNP) | VAF 56/722 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- EHD2 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPAS1 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- EPHB3 | c.2382T>G p.S794R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EPRS1 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 62/595 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERC2 | c.2591G>C p.S864T | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ERCC3 | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 46/416 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESPNL | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- EVI5L | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EVX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- F2R | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 53/509 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- F2RL2 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- F5 | c.2014A>C p.S672R | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- FAM124B | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- FAM78A | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); called by muse, mutect2
- FAT2 | c.5943G>T p.L1981F | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.444); called by muse, mutect2
- FAXC | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.391); called by muse, mutect2
- FBH1 | c.1988A>G p.Q663R (on ENST00000362091 / NM_178150.3; = p.Q714R on NM_032807.4) | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIBP | c.4A>T p.T2S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLNA | c.928A>C p.S310R | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- FMN2 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FN1 | c.5878A>G p.I1960V | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXD4L4 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 76/681 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FOXN4 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FUBP3 | c.1544A>T p.N515I | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT6 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GAPVD1 | c.357_371del p.K119_E123del | In Frame Del (DEL) | VAF 45/376 reads (12%) | called by mutect2, pindel
- GCKR | c.285+2T>A p.X95_splice | Splice Site (SNP) | VAF 72/613 reads (12%) | called by muse, mutect2, varscan2
- GCNT1 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFI1B | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2
- GGA2 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJB5 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GLI1 | c.1864A>C p.S622R | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- GNA13 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- GOLGA6D | c.1957T>G p.F653V | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GPR26 | c.721A>C p.K241Q | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GREM2 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA4 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRK5 | c.1_6del p.ME1_?2 | Translation Start Site (DEL) | VAF 26/195 reads (13%) | called by mutect2, pindel, varscan2
- GTF2A1 | c.1107A>T p.K369N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- H2BW2 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- HADHA | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 71/673 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HARBI1 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- HEATR5B | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- HECTD2 | c.1760T>G p.F587C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HIPK2 | c.2213T>G p.I738S | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); called by muse, mutect2
- HIVEP2 | c.4515A>C p.K1505N | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- HNF1A | c.1769-5T>A | Splice Region (SNP) | VAF 66/513 reads (13%) | called by mutect2, varscan2
- HORMAD1 | c.1106T>G p.V369G | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- HSPG2 | c.3962G>A p.G1321D | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICAM2 | c.461A>C p.E154A | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- IGHM | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 63/538 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ILF3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IQSEC2 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IRF2 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGA6 | c.958C>T p.P320S (on ENST00000442250; = p.P281S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/652 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNAB1 | c.288A>C p.K96N (on ENST00000490337 / NM_172160.3; = p.K85N on NM_003471.3) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); called by muse, mutect2
- KCNK13 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIAA0586 | c.1373A>C p.K458T (on ENST00000619416 / NM_001244190.2; = p.K473T on NM_014749.5) | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2
- KIAA1549L | c.3320T>A p.L1107Q (on ENST00000321505; = p.L1404Q on NM_012194.3) | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF4B | c.2779C>T p.H927Y | Missense Mutation (SNP) | VAF 58/540 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KISS1 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KLHL42 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 49/942 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- KLK14 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- KMT5B | c.1251A>C p.R417S | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); called by muse, mutect2
- KRBA2 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 73/356 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP16-1 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LAMA1 | c.5120A>T p.Q1707L | Missense Mutation (SNP) | VAF 83/536 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LAMB1 | c.4409T>G p.L1470R | Missense Mutation (SNP) | VAF 52/738 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- LMAN1L | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- LPIN1 | c.2196G>T p.M732I | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRRC32 | c.1601A>T p.Q534L | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LRRC45 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- LRRC69 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LVRN | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- LZTR1 | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 54/484 reads (11%) | called by muse, varscan2
- MACF1 | c.17219G>T p.G5740V (on ENST00000372915; = p.G3782V on NM_012090.5) | Missense Mutation (SNP) | VAF 24/279 reads (9%) | called by muse, mutect2
- MACF1 | c.18826A>G p.T6276A (on ENST00000372915; = p.T4321A on NM_012090.5) | Missense Mutation (SNP) | VAF 60/543 reads (11%) | called by muse, mutect2, varscan2
- MADD | c.4409A>G p.N1470S | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAEL | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 58/616 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- MAGEB6 | c.798C>A p.S266R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MAGEB6B | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANBA | c.2150T>G p.L717R (on ENST00000642252; = p.L671R on NM_005908.4) | Missense Mutation (SNP) | VAF 60/741 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAP7 | c.1498del p.E500Rfs*108 | Frame Shift Del (DEL) | VAF 30/238 reads (13%) | called by mutect2, pindel, varscan2
- MARK1 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 110/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARK1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 110/489 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK2 | c.417T>G p.D139E | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- MCF2L2 | c.854T>A p.L285H | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MDGA1 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- MDN1 | c.8488A>T p.R2830W | Missense Mutation (SNP) | VAF 75/553 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- MED12 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MEPE | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGA | c.3754A>T p.R1252* | Nonsense Mutation (SNP) | VAF 42/305 reads (14%) | called by muse, mutect2, varscan2
- MKRN2 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- MON2 | c.4046G>A p.G1349E | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.117); called by muse, mutect2
- MR1 | c.863T>G p.V288G | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MS4A14 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.15809T>C p.L5270P (on ENST00000379442; = p.L5127P on NM_001164462.1) | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- MUC16 | c.40028C>G p.P13343R | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC22 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.96); called by muse, mutect2, varscan2
- MXRA5 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYL10 | c.583-1G>T p.X195_splice | Splice Site (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- MYLIP | c.354A>T p.E118D | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO1F | c.2177A>C p.N726T | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MYO1H | c.2207C>A p.A736E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- MYOF | c.4908A>C p.E1636D | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MYPN | c.2911A>T p.I971L | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- N4BP2 | c.301A>C p.S101R | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NACA | c.391T>G p.L131V | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NDST4 | c.2252T>A p.I751K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK10 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NFIA | c.1483A>C p.S495R | Missense Mutation (SNP) | VAF 63/572 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NOTCH4 | c.3166T>G p.F1056V | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- NPAS3 | c.1600C>G p.H534D (on ENST00000356141 / NM_001164749.2; = p.H502D on NM_022123.3) | Missense Mutation (SNP) | VAF 77/496 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPR1 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- NRK | c.4172C>A p.P1391Q | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD3 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- ODF2 | c.1342T>C p.Y448H (on ENST00000434106 / NM_153433.2; = p.Y424H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.022); called by muse, mutect2
- OLIG2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR1K1 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OR1L8 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR1L8 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OR2Z1 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR51E2 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51F2 | c.24dup p.A9Cfs*2 | Frame Shift Ins (INS) | VAF 32/257 reads (12%) | called by mutect2, pindel, varscan2
- OR56B4 | c.659T>A p.V220E | Missense Mutation (SNP) | VAF 52/552 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- OR8H1 | c.530del p.F177Sfs*8 | Frame Shift Del (DEL) | VAF 30/263 reads (11%) | called by mutect2, varscan2
- PARP9 | c.1300A>C p.N434H | Missense Mutation (SNP) | VAF 41/881 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, mutect2
- PARVB | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PBRM1 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 73/516 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PCDHA9 | c.2321C>A p.P774Q | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCDHB5 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- PCDHGB4 | c.954del p.A319Qfs*7 | Frame Shift Del (DEL) | VAF 25/246 reads (10%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PCNT | c.8283G>C p.L2761F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCYT1B | c.1049C>A p.S350* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- PDAP1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 44/469 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2
- PDCD1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDE9A | c.1499C>A p.P500Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDPR | c.1508A>C p.K503T | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- PDZD4 | c.954A>T p.Q318H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PELI3 | c.881T>G p.I294S | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PGM2 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PGM2L1 | c.662T>C p.L221S | Missense Mutation (SNP) | VAF 74/810 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2
- PIGB | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- PKD1L3 | c.3527G>T p.S1176I | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKLR | c.781T>G p.L261V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PKNOX2 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- PLEKHA3 | c.178A>G p.R60G | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLPPR4 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- PLSCR5 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLSCR5 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PODXL | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); called by muse, mutect2
- POLQ | c.3205G>T p.G1069* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- POLR2F | c.401A>C p.N134T | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- POLR3D | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- POU5F1 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIA2 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2
- PPP4R4 | c.1611+1G>T p.X537_splice | Splice Site (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- PRDM9 | c.2334C>G p.C778W | Missense Mutation (SNP) | VAF 70/714 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRKAG3 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKAR1A | c.577A>G p.S193G | Missense Mutation (SNP) | VAF 102/1114 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2
- PRR12 | c.3108G>T p.L1036F (on ENST00000615927; = p.L1857F on NM_020719.3) | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCHD4 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- PTER | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTK2 | c.1298T>G p.F433C | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PTPRD | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRK | c.1853G>T p.R618I | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2
- R3HDM1 | c.2368T>C p.Y790H | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RASGRP4 | c.910A>G p.R304G | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RCOR1 | c.780-1G>T p.X260_splice | Splice Site (SNP) | VAF 65/581 reads (11%) | called by muse, mutect2, varscan2
- RELN | c.3294T>A p.C1098* | Nonsense Mutation (SNP) | VAF 96/682 reads (14%) | called by muse, mutect2, varscan2
- RELN | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 59/593 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RET | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RFPL4A | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.156); called by muse, mutect2
- RFX6 | c.693T>A p.Y231* | Nonsense Mutation (SNP) | VAF 46/534 reads (9%) | called by muse, mutect2
- RGPD8 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 70/747 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RGS12 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RLIM | c.1755A>C p.K585N | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RNF103 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 79/754 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- RNF212B | c.706T>G p.F236V | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2
- RP1L1 | c.5428C>T p.H1810Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RUSC1 | c.2192A>C p.E731A (on ENST00000368352 / NM_001105203.2; = p.E262A on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/412 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SALL2 | c.2742A>C p.E914D | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SCN4A | c.4858_4873del p.F1620Rfs*27 | Frame Shift Del (DEL) | VAF 34/401 reads (8%) | called by mutect2, pindel
- SCNN1D | c.917T>A p.L306Q (on ENST00000338555; = p.L470Q on NM_001130413.4) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDK2 | c.5476G>T p.G1826* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- SERPINA10 | c.1076G>T p.R359I | Missense Mutation (SNP) | VAF 70/521 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SERPINA3 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SETD3 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHPK | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2
- SIX4 | c.1183A>C p.K395Q | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SLC2A7 | c.474A>C p.E158D | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC30A10 | c.758T>A p.V253E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC7A14 | c.1893C>A p.C631* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- SOX30 | c.2238A>C p.E746D | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2
- SRCIN1 | c.671A>T p.E224V (on ENST00000621492; = p.E190V on NM_025248.3) | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRRM2 | c.1840A>G p.R614G | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- STRADA | c.253G>T p.V85L (on ENST00000336174 / NM_001363786.1; = p.V48L on NM_153335.6) | Missense Mutation (SNP) | VAF 48/648 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- SUCNR1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SV2A | c.120A>C p.E40D | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.184); called by muse, mutect2
- SVEP1 | c.9007C>A p.L3003M | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SYNPR | c.525C>G p.S175R | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SYPL2 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- SYT9 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- TAC3 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 91/703 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- TCHHL1 | c.1067A>G p.Y356C | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- TENM2 | c.4106T>A p.M1369K (on ENST00000518659 / NM_001122679.2; = p.M1130K on NM_001080428.3) | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TET1 | c.3590A>C p.N1197T | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TET3 | c.2199G>T p.Q733H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TJP1 | c.3682C>A p.P1228T | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TKTL2 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR5 | c.1781T>G p.L594R | Missense Mutation (SNP) | VAF 55/692 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TLR8 | c.417A>C p.Q139H (on ENST00000218032 / NM_138636.5; = p.Q157H on NM_016610.4) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TLR8 | c.2186C>A p.S729Y (on ENST00000218032 / NM_138636.5; = p.S747Y on NM_016610.4) | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TMEFF1 | c.1122T>A p.D374E | Missense Mutation (SNP) | VAF 43/410 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.138); called by muse, mutect2
- TMEM14C | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TMEM154 | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TMEM159 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 30/605 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM179 | c.458dup p.D154Gfs*180 | Frame Shift Ins (INS) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- TNK2 | c.1874A>T p.D625V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- TNS4 | c.2027A>T p.K676M | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRANK1 | c.6218T>G p.F2073C | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV8-7 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, varscan2
- TRERF1 | c.2750A>C p.K917T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM26 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRIM39 | c.871G>T p.G291* | Nonsense Mutation (SNP) | VAF 93/717 reads (13%) | called by muse, mutect2, varscan2
- TRIM9 | c.1986del p.N663Tfs*8 | Frame Shift Del (DEL) | VAF 44/441 reads (10%) | called by mutect2, pindel, varscan2
- TRMT13 | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2
- TRPA1 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 70/848 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TRPC4AP | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- TRPM1 | c.2682G>T p.W894C | Missense Mutation (SNP) | VAF 67/597 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TSG101 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 97/816 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.81321A>T p.R27107S (on ENST00000591111; = p.R19683S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | PolyPhen possibly damaging (0.447); called by muse, mutect2
- TUB | c.1082G>A p.G361E (on ENST00000299506 / NM_177972.3; = p.G416E on NM_003320.4) | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TYW3 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UAP1L1 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBAP2 | c.1969+4A>G | Splice Region (SNP) | VAF 51/351 reads (15%) | called by muse, mutect2, varscan2
- UGT1A3 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); called by mutect2, varscan2
- ULK1 | c.2599G>T p.A867S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UNC13A | c.4409A>C p.K1470T | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- USH2A | c.10922G>C p.R3641T | Missense Mutation (SNP) | VAF 82/1208 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.412); called by muse, mutect2
- USHBP1 | c.757del p.W253Gfs*80 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- USP47 | c.1363T>G p.S455A (on ENST00000399455 / NM_001372095.1; = p.S367A on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); called by muse, mutect2
- VAV1 | c.833T>A p.L278H | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VNN2 | c.967T>A p.Y323N | Missense Mutation (SNP) | VAF 67/588 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- WDR17 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); called by muse, mutect2
- WDR62 | c.1325T>G p.L442W | Missense Mutation (SNP) | VAF 69/600 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- WDR91 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- XIRP2 | c.8926G>T p.V2976F (on ENST00000628543; = p.V3151F on NM_152381.6) | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- XPNPEP2 | c.1516T>A p.F506I | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- XXYLT1 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLT1 | c.2102A>C p.K701T | Missense Mutation (SNP) | VAF 47/418 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ZAN | c.6187G>T p.G2063* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2
- ZBTB11 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB40 | c.2684G>C p.C895S | Missense Mutation (SNP) | VAF 69/471 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB47 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC12 | c.770A>C p.E257A | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- ZFC3H1 | c.4516A>C p.K1506Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZFX | c.1613T>C p.L538P | Missense Mutation (SNP) | VAF 98/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF221 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF256 | c.1640A>C p.Y547S | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, varscan2
- ZNF256 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF41 | c.1646A>C p.K549T | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF431 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 135/624 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF597 | c.1009A>C p.K337Q | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF674 | c.894T>G p.H298Q | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF727 | c.951T>A p.C317* | Nonsense Mutation (SNP) | VAF 24/310 reads (8%) | called by muse, mutect2
- ZNF804A | c.2042A>T p.Y681F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF841 | c.2110C>T p.P704S (on ENST00000426391 / NM_001369830.1; = p.P820S on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF853 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- AC098582.1 | c.2455T>C p.L819= | Silent (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- ACAA1 | c.690C>G p.V230= | Silent (SNP) | VAF 51/420 reads (12%) | called by muse, mutect2, varscan2
- ACVR2B | c.1116A>T p.G372= | Silent (SNP) | VAF 67/652 reads (10%) | called by muse, mutect2, varscan2
- ADGRB2 | c.994C>A p.R332= | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, varscan2
- ADGRE1 | c.2193G>T p.V731= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as rs778718718; called by muse, mutect2, varscan2
- ADGRL2 | c.2043C>A p.I681= (on ENST00000370717 / NM_001366005.1; = p.I668= on NM_012302.4) | Silent (SNP) | VAF 48/439 reads (11%) | called by muse, mutect2, varscan2
- ADSL | c.75G>A p.E25= | Silent (SNP) | VAF 29/332 reads (9%) | catalogued as rs1057522536; ClinVar: likely benign; called by muse, mutect2
- AGXT | c.564G>T p.L188= | Silent (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- AHNAK | c.6453G>T p.V2151= | Silent (SNP) | VAF 77/660 reads (12%) | called by mutect2, varscan2
- ALOXE3 | c.1353G>A p.A451= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1276445364; called by muse, mutect2, varscan2
- ANKRD35 | c.1092T>G p.P364= | Silent (SNP) | VAF 33/251 reads (13%) | catalogued as rs1258396349; called by muse, mutect2, varscan2
- ANKRD35 | c.780C>T p.S260= | Silent (SNP) | VAF 51/628 reads (8%) | called by muse, mutect2
- ARAP3 | c.3498T>G p.T1166= | Silent (SNP) | VAF 35/413 reads (8%) | called by muse, mutect2
- ARHGEF11 | c.1434C>T p.T478= | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as rs1013325134, COSV63812593; called by muse, mutect2, varscan2
- ASGR1 | c.348G>T p.L116= | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as rs1017326929; called by muse, varscan2
- BAHCC1 | c.3798G>A p.Q1266= | Silent (SNP) | VAF 57/262 reads (22%) | called by muse, mutect2, varscan2
- BTAF1 | c.45T>A p.T15= | Silent (SNP) | VAF 29/311 reads (9%) | called by muse, mutect2
- CCDC60 | c.516C>G p.T172= | Silent (SNP) | VAF 46/450 reads (10%) | called by muse, mutect2, varscan2
- CD2 | c.810T>G p.A270= | Silent (SNP) | VAF 41/307 reads (13%) | catalogued as COSV65644309; called by muse, mutect2, varscan2
- CDH10 | c.2059C>A p.R687= | Silent (SNP) | VAF 104/1112 reads (9%) | catalogued as rs768194920, COSV52574627, COSV52575923; called by muse, mutect2
- CDH4 | c.960C>A p.T320= | Silent (SNP) | VAF 36/340 reads (11%) | called by muse, mutect2
- CDKN2C | c.325T>C p.L109= | Silent (SNP) | VAF 61/483 reads (13%) | called by muse, mutect2, varscan2
- CHRNA1 | c.156C>T p.T52= | Silent (SNP) | VAF 92/747 reads (12%) | catalogued as rs1371157689, COSV53682562; called by muse, mutect2, varscan2
- CLCN6 | c.2271A>T p.G757= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- COL15A1 | c.528C>T p.L176= | Silent (SNP) | VAF 50/673 reads (7%) | catalogued as rs751192017, COSV66647096; called by muse, mutect2
- COL6A6 | c.1212G>C p.L404= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- CPN1 | c.1020G>A p.Q340= | Silent (SNP) | VAF 52/530 reads (10%) | called by muse, mutect2, varscan2
- CPQ | c.684G>A p.K228= | Silent (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2, varscan2
- CSMD3 | c.6396C>A p.P2132= (on ENST00000297405 / NM_001363185.1; = p.P2028= on NM_052900.3) | Silent (SNP) | VAF 43/600 reads (7%) | catalogued as COSV52326876; called by muse, mutect2
- CXCR1 | c.1023T>G p.S341= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- CYP2C8 | c.1101C>T p.P367= | Silent (SNP) | VAF 60/701 reads (9%) | called by muse, mutect2
- DDX43 | c.1002A>G p.G334= | Silent (SNP) | VAF 38/351 reads (11%) | called by muse, mutect2, varscan2
- DEDD | c.202T>C p.L68= | Silent (SNP) | VAF 42/447 reads (9%) | catalogued as rs778571118; called by muse, mutect2
- DNAH8 | c.10818T>A p.A3606= | Silent (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- DPY19L2 | c.2035C>A p.R679= | Silent (SNP) | VAF 26/339 reads (8%) | catalogued as COSV61041179, COSV61042180; called by muse, mutect2
- DSC1 | c.834T>A p.R278= | Silent (SNP) | VAF 43/375 reads (11%) | called by muse, mutect2, varscan2
- E2F1 | c.1212A>G p.P404= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- ELAPOR2 | c.267G>T p.V89= | Silent (SNP) | VAF 52/704 reads (7%) | called by muse, mutect2
- ENTPD6 | c.139C>T p.L47= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as COSV100737122; called by muse, mutect2, varscan2
- EPAS1 | c.1020C>T p.V340= | Silent (SNP) | VAF 45/448 reads (10%) | called by muse, mutect2
- EVC2 | c.1821C>A p.T607= | Silent (SNP) | VAF 65/495 reads (13%) | catalogued as rs1229046589, COSV60388522; called by muse, mutect2, varscan2
- FER1L6 | c.1329T>A p.T443= | Silent (SNP) | VAF 54/423 reads (13%) | called by muse, mutect2, varscan2
- FOSB | c.273C>A p.P91= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- FOXD3 | c.183G>T p.V61= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- FRG2 | c.486G>T p.R162= | Silent (SNP) | VAF 78/630 reads (12%) | called by muse, mutect2, varscan2
- GLRA3 | c.996G>A p.L332= | Silent (SNP) | VAF 64/603 reads (11%) | called by muse, mutect2, varscan2
- GPRASP1 | c.399G>A p.K133= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- HEATR4 | c.2985C>T p.S995= | Silent (SNP) | VAF 35/391 reads (9%) | catalogued as rs752748363, COSV58573100; called by muse, mutect2
- HINFP | c.1083C>T p.T361= | Silent (SNP) | VAF 32/307 reads (10%) | catalogued as rs199743668; called by muse, mutect2, varscan2
- IGF2R | c.3147G>T p.G1049= | Silent (SNP) | VAF 52/427 reads (12%) | called by muse, mutect2, varscan2
- IRGQ | c.1737C>T p.F579= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs1215943714, COSV60670163; called by muse, mutect2
- ITGA2 | c.2799G>T p.L933= | Silent (SNP) | VAF 106/867 reads (12%) | called by muse, mutect2, varscan2
- ITPR1 | c.3642G>T p.V1214= (on ENST00000354582; = p.V1199= on NM_002222.7) | Silent (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- KCNA10 | c.267C>A p.I89= | Silent (SNP) | VAF 25/305 reads (8%) | called by muse, mutect2
- KCP | c.4362G>A p.R1454= (on ENST00000620378; = p.R1578= on NM_001366122.1) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1324543901; called by muse, mutect2, varscan2
- KDM4E | c.363A>T p.R121= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- KIF27 | c.513C>T p.A171= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1450777498; called by muse, mutect2, varscan2
- KISS1 | c.81T>G p.S27= | Silent (SNP) | VAF 63/582 reads (11%) | called by muse, mutect2, varscan2
- KRT33B | c.780C>A p.S260= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as rs1293192673; called by muse, mutect2, varscan2
- LRP10 | c.111A>G p.E37= | Silent (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1986C>T p.S662= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs908727676; called by muse, mutect2, varscan2
- MAGEB16 | c.798C>A p.A266= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- MAP3K7 | c.471G>A p.L157= | Silent (SNP) | VAF 68/383 reads (18%) | catalogued as COSV65232582; called by muse, mutect2, varscan2
- MCOLN1 | c.123T>G p.L41= | Silent (SNP) | VAF 52/369 reads (14%) | called by muse, mutect2, varscan2
- MINAR1 | c.267G>A p.T89= | Silent (SNP) | VAF 97/371 reads (26%) | catalogued as rs201787786; called by muse, mutect2, varscan2
- MTMR4 | c.2451A>T p.P817= | Silent (SNP) | VAF 85/730 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.23943T>G p.T7981= | Silent (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- MYO1G | c.2676A>T p.T892= | Silent (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2, varscan2
- MYT1L | c.1575G>T p.L525= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- NDUFAF6 | c.36G>T p.P12= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- NF1 | c.4791G>A p.G1597= (on ENST00000358273 / NM_001042492.3; = p.G1576= on NM_000267.3) | Silent (SNP) | VAF 51/423 reads (12%) | catalogued as rs1412795566; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR13C5 | c.390G>T p.L130= | Silent (SNP) | VAF 43/246 reads (17%) | called by muse, mutect2, varscan2
- OR2A4 | c.216C>T p.Y72= | Silent (SNP) | VAF 30/484 reads (6%) | catalogued as rs762454232; called by muse, mutect2
- OR2A5 | c.861C>A p.P287= | Silent (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- OR2L8 | c.138T>A p.L46= | Silent (SNP) | VAF 48/488 reads (10%) | called by muse, mutect2
- OR2M3 | c.546C>A p.P182= | Silent (SNP) | VAF 29/288 reads (10%) | called by muse, mutect2, varscan2
- OR2T33 | c.666T>C p.A222= | Silent (SNP) | VAF 33/382 reads (9%) | catalogued as COSV100531711; called by muse, mutect2, varscan2
- OR2Z1 | c.471C>A p.S157= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as COSV60693484; called by muse, mutect2, varscan2
- OR51D1 | c.366C>A p.A122= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV62914935; called by muse, mutect2, varscan2
- OR5F1 | c.579C>A p.I193= | Silent (SNP) | VAF 21/232 reads (9%) | catalogued as rs1317772323, COSV53545369, COSV53547790; called by muse, mutect2
- OXT | c.6C>A p.A2= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1986G>T p.T662= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as rs1554122629; called by muse, mutect2, varscan2
- PCDHA6 | c.1461C>T p.N487= | Silent (SNP) | VAF 76/680 reads (11%) | catalogued as rs1302023406; called by muse, mutect2, varscan2
- PCDHB6 | c.1767G>T p.A589= | Silent (SNP) | VAF 39/274 reads (14%) | catalogued as COSV99170159; called by mutect2, varscan2
- PCDHGA4 | c.1560C>T p.Y520= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as rs886604200, COSV54033908; called by muse, mutect2, varscan2
- PCDHGB6 | c.273C>T p.D91= | Silent (SNP) | VAF 67/616 reads (11%) | called by muse, mutect2, varscan2
- PCSK9 | c.267G>A p.S89= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs373551845; ClinVar: likely benign; called by muse, mutect2, varscan2
- PGBD2 | c.411A>G p.Q137= | Silent (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2, varscan2
- PLA2R1 | c.1512A>C p.A504= | Silent (SNP) | VAF 42/430 reads (10%) | catalogued as rs141553462; called by muse, mutect2
- PLXNB1 | c.4314G>A p.E1438= | Silent (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2
- POP1 | c.2587C>T p.L863= | Silent (SNP) | VAF 69/496 reads (14%) | catalogued as rs749966603; called by muse, mutect2, varscan2
- PPP2R3A | c.2043A>T p.P681= | Silent (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- PSG1 | c.177C>A p.P59= | Silent (SNP) | VAF 63/258 reads (24%) | catalogued as COSV54944301, COSV54955194; called by muse, mutect2, varscan2
- PSG6 | c.1281C>T p.T427= | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- PWWP2A | c.1020T>C p.S340= | Silent (SNP) | VAF 58/439 reads (13%) | catalogued as rs1407713480, COSV100193741; called by muse, mutect2, varscan2
- PYGM | c.1737C>T p.L579= | Silent (SNP) | VAF 53/342 reads (15%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.651A>G p.Q217= | Silent (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2
- RASEF | c.256C>T p.L86= | Silent (SNP) | VAF 44/195 reads (23%) | called by muse, mutect2, varscan2
- RBM23 | c.1089A>T p.A363= (on ENST00000359890 / NM_001077351.2; = p.A347= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs773425201; called by muse, mutect2
- RPRD1B | c.669T>A p.A223= | Silent (SNP) | VAF 32/202 reads (16%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.702G>T p.G234= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- RRBP1 | c.3489A>G p.A1163= (on ENST00000377813 / NM_001365613.2; = p.A730= on NM_004587.3) | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs776950671; called by muse, varscan2
- RSL1D1 | c.498C>G p.P166= | Silent (SNP) | VAF 48/360 reads (13%) | called by muse, mutect2, varscan2
- RTN4 | c.2226T>G p.S742= | Silent (SNP) | VAF 49/323 reads (15%) | catalogued as rs1181419274; called by muse, mutect2, varscan2
- RYR3 | c.393C>T p.D131= | Silent (SNP) | VAF 44/511 reads (9%) | catalogued as rs183923528, COSV66809790; called by muse, mutect2
- RYR3 | c.6888C>G p.G2296= (on ENST00000389232; = p.G2297= on NM_001036.6) | Silent (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- SCAF1 | c.3648G>T p.R1216= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- SCFD1 | c.1128T>G p.S376= | Silent (SNP) | VAF 50/544 reads (9%) | catalogued as COSV100356655; called by muse, mutect2
- SEMA4F | c.117G>T p.S39= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- SLC12A5 | c.591A>G p.P197= (on ENST00000454036 / NM_001134771.2; = p.P174= on NM_020708.5) | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- SLC18A2 | c.687C>T p.A229= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1391892362, COSV100041722; called by muse, mutect2, varscan2
- SLC24A1 | c.1044T>G p.P348= | Silent (SNP) | VAF 63/574 reads (11%) | called by muse, mutect2, varscan2
- SLC25A23 | c.510A>T p.T170= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- SLC25A28 | c.498G>T p.G166= | Silent (SNP) | VAF 58/504 reads (12%) | called by muse, mutect2, varscan2
- SLC35G5 | c.819G>A p.A273= | Silent (SNP) | VAF 49/374 reads (13%) | catalogued as rs147410277; called by muse, mutect2, varscan2
- SLC4A8 | c.540G>C p.L180= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as COSV60656617; called by muse, mutect2, varscan2
- SLC6A8 | c.12G>A p.K4= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.792C>T p.P264= | Silent (SNP) | VAF 33/392 reads (8%) | called by muse, mutect2
- SORBS1 | c.1560T>C p.D520= (on ENST00000361941 / NM_001034954.2; = p.D310= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- SPEF2 | c.3408T>C p.N1136= | Silent (SNP) | VAF 84/647 reads (13%) | called by muse, mutect2, varscan2
- SPEN | c.567A>C p.R189= | Silent (SNP) | VAF 81/737 reads (11%) | called by muse, mutect2, varscan2
- SPTA1 | c.4887G>A p.L1629= | Silent (SNP) | VAF 72/799 reads (9%) | called by muse, mutect2
- STYXL2 | c.862C>A p.R288= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs776576712, COSV99609493; called by muse, mutect2, varscan2
- SYNE1 | c.2832G>T p.R944= (on ENST00000367255 / NM_182961.4; = p.R951= on NM_033071.3) | Silent (SNP) | VAF 36/360 reads (10%) | catalogued as rs765265654, COSV55027705; called by muse, mutect2
- TCF7L2 | c.1071C>T p.F357= (on ENST00000355995 / NM_001367943.1; = p.F334= on NM_030756.5) | Silent (SNP) | VAF 48/318 reads (15%) | catalogued as COSV53337214; called by muse, mutect2, varscan2
- TG | c.4020C>G p.T1340= | Silent (SNP) | VAF 70/900 reads (8%) | catalogued as rs995728479; called by muse, mutect2
- THAP6 | c.106A>C p.R36= | Silent (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- THSD7A | c.1987C>A p.R663= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV70263921; called by muse, mutect2, varscan2
- TIAM1 | c.2874C>A p.L958= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- TNXB | c.7731T>C p.F2577= (on ENST00000647633; = p.F2330= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/537 reads (11%) | called by muse, mutect2, varscan2
- TOR3A | c.600G>A p.T200= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs756907840; called by muse, mutect2
- TRPC6 | c.519T>C p.Y173= | Silent (SNP) | VAF 72/829 reads (9%) | called by muse, mutect2
- TRPV4 | c.2127G>A p.L709= | Silent (SNP) | VAF 32/299 reads (11%) | catalogued as COSV55686775; called by muse, mutect2, varscan2
- TXLNB | c.705G>T p.R235= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
- VWA7 | c.1851T>C p.P617= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- WNK2 | c.4710G>A p.S1570= (on ENST00000297954 / NM_001282394.1; = p.S1533= on NM_006648.3) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs750204095, COSV52950151; called by muse, varscan2
- XKR3 | c.1206A>G p.P402= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as rs1569033852; called by muse, mutect2, varscan2
- ZC3H12A | c.1401T>G p.P467= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ZNF236 | c.4341G>T p.V1447= | Silent (SNP) | VAF 75/554 reads (14%) | called by muse, mutect2, varscan2
- ZNF275 | c.576G>A p.K192= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ZNF365 | c.1030A>C p.R344= | Silent (SNP) | VAF 43/384 reads (11%) | called by muse, mutect2, varscan2
- ZNF433 | c.1764A>G p.K588= | Silent (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- ZNF75D | c.621G>A p.Q207= | Silent (SNP) | VAF 36/309 reads (12%) | catalogued as COSV100883708; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1307G>C | Intron (SNP) | VAF 11/120 reads (9%) | catalogued as COSV66929776; called by muse, mutect2
- AHSA2P | n.1698T>A | RNA (SNP) | VAF 30/351 reads (9%) | called by muse, mutect2
- AL133467.6 | chr14:95668323 A>T | 5'Flank (SNP) | VAF 47/380 reads (12%) | called by muse, mutect2, varscan2
- ALG2 | c.*157C>T | 3'UTR (SNP) | VAF 74/804 reads (9%) | called by muse, mutect2
- AQP3 | c.492+27A>C | Intron (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- ARHGAP23P1 | chr16:33938453 G>T | 5'Flank (SNP) | VAF 27/367 reads (7%) | called by muse, mutect2, varscan2
- ASB10 | chr7:151187434 del C | 5'Flank (DEL) | VAF 23/143 reads (16%) | called by mutect2, varscan2
- ASB13 | c.518-544T>G | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, varscan2
- ASH1L | c.5828+4626A>T | Intron (SNP) | VAF 63/455 reads (14%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1032+11G>T | Intron (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- BAGE2 | n.168G>T | RNA (SNP) | VAF 46/872 reads (5%) | called by muse, mutect2
- BEAN1 | chr16:66482892 A>G | 3'Flank (SNP) | VAF 50/405 reads (12%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3119G>T | Intron (SNP) | VAF 50/538 reads (9%) | called by muse, mutect2
- C1S | c.213+36A>G | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- C3orf18 | c.*818A>C | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- C3orf33 | c.114+433C>G | Intron (SNP) | VAF 51/314 reads (16%) | called by muse, mutect2, varscan2
- C6orf201 | c.285-6376T>G | Intron (SNP) | VAF 35/432 reads (8%) | called by muse, mutect2
- CACNB2 | c.120+348C>A | Intron (SNP) | VAF 49/290 reads (17%) | catalogued as COSV56621646; called by muse, mutect2, varscan2
- CAPN1 | chr11:65214117 A>C | 3'Flank (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- CATIP | c.320-56T>G | Intron (SNP) | VAF 24/456 reads (5%) | called by muse, mutect2
- CHRNA4 | c.*2813del | 3'UTR (DEL) | VAF 68/576 reads (12%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.*1515C>T | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- CNIH1 | c.-7C>T | 5'UTR (SNP) | VAF 21/148 reads (14%) | catalogued as rs370210998; called by muse, mutect2, varscan2
- CRAT | c.28-692A>G | Intron (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- DARS2 | c.*21A>C | 3'UTR (SNP) | VAF 19/404 reads (5%) | called by muse, mutect2
- DCHS2 | n.307A>T | RNA (SNP) | VAF 47/511 reads (9%) | called by muse, mutect2
- DGKZ | c.1009-134C>T | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- DMKN | c.1360-21T>G | Intron (SNP) | VAF 35/304 reads (12%) | called by muse, mutect2, varscan2
- DNMT1 | c.995+29A>C | Intron (SNP) | VAF 33/349 reads (9%) | called by muse, mutect2
- DPH1 | c.62-22T>C | Intron (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- DPYSL2 | chr8:26577224 C>T | 5'Flank (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- ERCC3 | c.2065-13T>C | Intron (SNP) | VAF 52/600 reads (9%) | called by muse, mutect2
- FAP | c.1402+547A>T | Intron (SNP) | VAF 71/486 reads (15%) | called by muse, mutect2, varscan2
- FDX2 | c.-9A>T | 5'UTR (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- FRMPD2B | n.805G>T | RNA (SNP) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- FTL | c.*7T>G | 3'UTR (SNP) | VAF 45/385 reads (12%) | catalogued as rs3211587; called by muse, mutect2, varscan2
- GMFG | c.200+24G>T | Intron (SNP) | VAF 33/362 reads (9%) | called by muse, mutect2
- GVINP1 | n.6463G>T | RNA (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1138G>C | RNA (SNP) | VAF 42/338 reads (12%) | called by muse, mutect2, varscan2
- IBTK | c.3431+61A>G | Intron (SNP) | VAF 59/524 reads (11%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3115G>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55167748; called by muse, mutect2
- IL10RA | c.*27T>G | 3'UTR (SNP) | VAF 99/790 reads (13%) | called by muse, mutect2, varscan2
- INTS8 | c.-135A>G | 5'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as rs1254477228; called by muse, mutect2, varscan2
- KIAA1755 | c.2269-68G>A | Intron (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- KIRREL3 | c.56-118983C>A | Intron (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- LYRM7 | c.-70T>A | 5'UTR (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2, varscan2
- MAGEA3 | c.-75G>A | 5'UTR (SNP) | VAF 152/979 reads (16%) | called by muse, mutect2, varscan2
- MEIS1 | c.*130C>T | 3'UTR (SNP) | VAF 70/390 reads (18%) | called by muse, mutect2, varscan2
- MRPL3 | c.-149C>T | 5'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2
- MTRNR2L6 | chr7:142671132 G>T | 3'Flank (SNP) | VAF 61/454 reads (13%) | catalogued as rs772010346; called by muse, mutect2, varscan2
- MYH11 | c.2521-37C>A | Intron (SNP) | VAF 99/409 reads (24%) | called by muse, mutect2, varscan2
- NDUFS2 | c.987-32G>A | Intron (SNP) | VAF 36/396 reads (9%) | called by muse, mutect2
- NRXN1 | c.3365-110235G>T | Intron (SNP) | VAF 31/292 reads (11%) | called by muse, mutect2, varscan2
- OR2L1P | n.631C>A | RNA (SNP) | VAF 28/255 reads (11%) | called by muse, varscan2
- OR2L1P | n.788G>C | RNA (SNP) | VAF 36/344 reads (10%) | called by muse, varscan2
- OR2P1P | chr6:29076475 A>T | 5'Flank (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- PIN1 | c.-4G>A | 5'UTR (SNP) | VAF 18/146 reads (12%) | catalogued as rs1191514281; called by muse, mutect2, varscan2
- PLEKHA3 | c.775+1208A>G | Intron (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- PLEKHS1 | chr10:113780650 G>T | 3'Flank (SNP) | VAF 46/354 reads (13%) | catalogued as COSV63056305; called by muse, mutect2, varscan2
- POLM | c.*66T>A | 3'UTR (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- PPP1R12C | c.1765-20T>G | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- PTPRT | c.2983-738G>T | Intron (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.*1304G>T | 3'UTR (SNP) | VAF 37/283 reads (13%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40549612 C>G | 3'Flank (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- RPS6KL1 | c.1539+35T>C | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- RXFP1 | c.465-851C>T | Intron (SNP) | VAF 53/512 reads (10%) | catalogued as rs998316940; called by muse, mutect2, varscan2
- SARDH | c.2496-38G>C | Intron (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2, varscan2
- SCN8A | c.3820-401C>A | Intron (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- SLC27A1 | c.1206+100G>T | Intron (SNP) | VAF 45/320 reads (14%) | called by muse, mutect2, varscan2
22 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 22 other) are not listed here.
